Somatic mutation profile of tumor specimen TCGA-3U-A98H-01A (aliquot TCGA-3U-A98H-01A-11D-A39R-32) from TCGA case TCGA-3U-A98H, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 57.6 years (21,034 days).
Specimen TCGA-3U-A98H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44d2ad11-a3d8-46f0-9f25-9ad07f926e2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3U-A98H-10A (Blood Derived Normal), aliquot TCGA-3U-A98H-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65edfddf-0e73-49a3-9bd1-efa61c120804

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.551G>A p.W184* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as rs1555993293, CM961031, COSV58527745; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.505del p.H169Tfs*18 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | catalogued as COSV56233385; called by mutect2, pindel, varscan2
- EGLN1 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 73/507 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as CD080824, COSV64147751; called by muse, mutect2, varscan2
- MAPK13 | c.762+1G>T p.X254_splice | Splice Site (SNP) | VAF 21/136 reads (15%) | catalogued as COSV99274825; called by muse, mutect2, varscan2
- SETD2 | c.3859C>T p.Q1287* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV57432172, COSV57456378; called by muse, mutect2, varscan2
- AKAP12 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BCOR | c.1460dup p.S488Ifs*11 | Frame Shift Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- KAT6B | c.6220T>C p.*2074Qext*16 | Nonstop Mutation (SNP) | VAF 28/140 reads (20%) | called by muse, mutect2, varscan2
- OR4D6 | c.488T>C p.M163T | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PLXNB2 | c.225_228dup p.K77Qfs*14 | Frame Shift Ins (INS) | VAF 53/263 reads (20%) | called by mutect2, pindel, varscan2
- RGS5 | c.217+2T>A p.X73_splice | Splice Site (SNP) | VAF 13/82 reads (16%) | called by muse, varscan2
- SEC24B | c.1349_1355del p.P450Lfs*50 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- C19orf57 | c.615G>A p.Q205= | Silent (SNP) | VAF 47/246 reads (19%) | called by muse, mutect2, varscan2
- GLS | c.162C>T p.L54= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2
- JMJD4 | c.615C>T p.S205= | Silent (SNP) | VAF 49/188 reads (26%) | catalogued as rs928570981, COSV100248234; called by muse, mutect2, varscan2
- PARP12 | c.1263C>T p.D421= | Silent (SNP) | VAF 85/278 reads (31%) | catalogued as rs369328541; called by muse, mutect2, varscan2
- TRIM25 | c.1113G>A p.A371= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as rs921486132; called by muse, mutect2, varscan2
